Somatic mutation profile of tumor specimen TCGA-A3-3313-01A (aliquot TCGA-A3-3313-01A-01W-0886-08) from TCGA case TCGA-A3-3313, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.0 years (21,556 days).
Specimen TCGA-A3-3313-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 121132f9-1160-4ba7-a1ac-43436ab8b9a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3313-11A (Solid Tissue Normal), aliquot TCGA-A3-3313-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d183884c-d1d3-41ff-87d7-74069466c321

The open-access MAF lists 123 somatic variants for this specimen: 100 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 21, Frame Shift Ins 8, Nonsense Mutation 6, Frame Shift Del 6, Splice Region 2, 3'UTR 1, RNA 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCPH1 | c.74C>G p.S25* | Nonsense Mutation (SNP) | VAF 56/103 reads (54%) | catalogued as rs121434305, CM021634; ClinVar: pathogenic; called by muse, mutect2
- AARS2 | c.2194C>T p.H732Y | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs946886065; called by muse, mutect2
- ADAM12 | c.1209C>A p.S403R | Missense Mutation (SNP) | VAF 34/773 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV64114026; called by muse, mutect2
- ATP8A1 | c.367C>G p.R123G | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52530727; called by muse, mutect2, varscan2
- BUB1B | c.751G>C p.A251P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV55009570; called by muse, mutect2, varscan2
- CDH7 | c.1975G>T p.G659* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV59881280; called by mutect2, varscan2
- COG1 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs751959598; called by muse, varscan2
- DDX60L | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as COSV52714629; called by muse, mutect2, varscan2
- EPB41L3 | c.2829del p.K943Nfs*9 | Frame Shift Del (DEL) | VAF 31/107 reads (29%) | catalogued as rs1567966618; called by mutect2, pindel, varscan2
- HHIPL1 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58091791; called by muse, mutect2, varscan2
- KRT28 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs923265611; called by muse, mutect2, varscan2
- LATS2 | c.1031dup p.Q345Afs*17 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs746424000; called by pindel, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 35/221 reads (16%) | catalogued as rs746133895; called by mutect2, varscan2
- LRIG3 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.77); catalogued as COSV57862447; called by muse, varscan2
- MCM2 | c.2236A>T p.M746L | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1370918842; called by muse, mutect2, varscan2
- NR4A2 | c.325dup p.Q109Pfs*3 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | catalogued as rs774629025; called by mutect2, varscan2
- PEX12 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 363/1196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56778309; called by muse, mutect2, varscan2
- PKHD1 | c.8600C>T p.S2867F | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs765481635; called by muse, mutect2, varscan2
- PRKDC | c.2222T>C p.I741T | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1456557309, COSV100038511; called by muse, mutect2, varscan2
- SLC9A8 | c.844T>G p.S282A | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV64288379; called by muse, mutect2, varscan2
- SLC9A9 | c.1854G>T p.K618N | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.521); catalogued as COSV57247136; called by muse, mutect2, varscan2
- TNFRSF11B | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs757952532; called by muse, mutect2, varscan2
- TTN | c.22733C>T p.P7578L (on ENST00000591111; = p.P6651L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | PolyPhen benign (0.015); catalogued as COSV60168543; called by muse, mutect2, varscan2
- UBR2 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 397/599 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65768610; called by muse, mutect2, varscan2
- UTP11 | c.496T>A p.F166I | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV65951969; called by muse, mutect2
- XKR8 | c.635G>A p.W212* | Nonsense Mutation (SNP) | VAF 6/144 reads (4%) | catalogued as COSV65835187; called by muse, mutect2
- ZFHX4 | c.2483A>G p.N828S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as rs1299909189; called by muse, mutect2, varscan2
- ZNF789 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as rs1171134141; called by muse, mutect2, varscan2
- AARS1 | c.1210A>G p.K404E | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ADAM11 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP32 | c.4906C>T p.Q1636* (on ENST00000310343 / NM_001378025.1; = p.Q1287* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- AVIL | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- C8A | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CACNA1G | c.3507G>T p.K1169N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, varscan2
- CDC16 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- CNGA2 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTBP2 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DAPL1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- DIP2C | c.3974T>A p.L1325Q | Missense Mutation (SNP) | VAF 127/413 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF1 | c.195+2T>C p.X65_splice | Splice Site (SNP) | VAF 58/157 reads (37%) | called by muse, mutect2, varscan2
- ENPP4 | c.980dup p.N327Kfs*2 | Frame Shift Ins (INS) | VAF 130/251 reads (52%) | called by mutect2, pindel, varscan2
- EPS15L1 | c.517A>T p.I173F | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ERICH6 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FAT4 | c.5635_5636insATTT p.I1879Nfs*5 | Frame Shift Ins (INS) | VAF 33/144 reads (23%) | called by mutect2, pindel, varscan2
- FBN2 | c.6277G>A p.G2093R | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); called by muse, mutect2
- FOXRED2 | c.1622C>A p.T541N | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- GALT | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, varscan2
- GLIS2 | c.218_220dup p.F73dup | In Frame Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- GMDS | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 14/461 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2
- GPR179 | c.5345C>A p.A1782D (on ENST00000621958; = p.A1781D on NM_001004334.4) | Missense Mutation (SNP) | VAF 183/335 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- GRSF1 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GUSB | c.1703_1709del p.Q568Lfs*24 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel*, varscan2
- HNRNPU | c.899A>G p.Y300C (on ENST00000283179; = p.Y362C on NM_004501.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSD17B2 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IQGAP3 | c.2811C>G p.D937E | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIF7 | c.2316G>T p.K772N | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- KLF13 | c.590T>C p.F197S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA5 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LARS2 | c.1529A>G p.K510R | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by mutect2, varscan2
- MCPH1 | c.72T>A p.Y24* | Nonsense Mutation (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2
- MPRIP | c.2052G>C p.E684D | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- MTREX | c.1328_1345delinsCT p.H443Pfs*16 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by pindel, varscan2*
- MYCBP2 | c.2791C>A p.H931N (on ENST00000357337; = p.H969N on NM_015057.5) | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NUMA1 | c.364A>G p.K122E | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- OPA1 | c.2686_2689dup p.R897Ifs*2 (on ENST00000361510 / NM_130837.3; = p.R842Ifs*2 on NM_015560.3) | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- PDIA6 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3C2A | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2
- PLEKHA3 | c.614T>G p.M205R | Missense Mutation (SNP) | VAF 159/381 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- PLIN2 | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 20/507 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- POC1B | c.1305T>G p.I435M | Missense Mutation (SNP) | VAF 204/553 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, varscan2
- RGS8 | c.353C>T p.P118L (on ENST00000367556 / NM_001369564.2; = p.P136L on NM_033345.3) | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RHOV | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2
- RICTOR | c.4568G>C p.C1523S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RNF6 | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 139/434 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RORA | c.390A>T p.L130F (on ENST00000335670 / NM_134261.3; = p.L155F on NM_002943.3) | Missense Mutation (SNP) | VAF 288/881 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RPS19 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 135/212 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- SAAL1 | c.201dup p.E68Rfs*5 | Frame Shift Ins (INS) | VAF 160/605 reads (26%) | called by pindel, varscan2
- SEC14L1 | c.1790_1791dup p.V598Kfs*16 | Frame Shift Ins (INS) | VAF 65/258 reads (25%) | called by mutect2, pindel, varscan2
- SH2D2A | c.732G>C p.R244S | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SLC12A8 | c.1766dup p.Y589* | Nonsense Mutation (INS) | VAF 36/157 reads (23%) | called by mutect2, pindel, varscan2
- SLC3A2 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SLIT1 | c.1124G>A p.G375D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SNX14 | c.2603del p.K868Sfs*12 (on ENST00000314673 / NM_001350535.1; = p.K815Sfs*12 on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/24 reads (54%) | called by mutect2, pindel, varscan2
- SYCE1 | c.389T>C p.L130S (on ENST00000343131 / NM_001143764.3; = p.L94S on NM_130784.3) | Missense Mutation (SNP) | VAF 291/831 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TCOF1 | c.3107G>T p.S1036I (on ENST00000377797 / NM_001135243.1; = p.S959I on NM_000356.4) | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TENT2 | c.1285T>G p.Y429D | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TMC5 | c.2114T>A p.I705N (on ENST00000396229 / NM_001105248.1; = p.I459N on NM_024780.5) | Missense Mutation (SNP) | VAF 151/455 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TMEM131L | c.2620del p.T874Rfs*12 | Frame Shift Del (DEL) | VAF 110/400 reads (28%) | called by mutect2, pindel, varscan2
- TNNT2 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- UBR2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 386/545 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR5 | c.1320_1324del p.N440Kfs*8 | Frame Shift Del (DEL) | VAF 147/387 reads (38%) | called by mutect2, pindel, varscan2
- UNC13C | c.2805A>C p.L935F | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- USP30 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.818); called by muse, mutect2
- VARS2 | c.2160C>A p.F720L | Missense Mutation (SNP) | VAF 159/361 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- VPS33A | c.1167C>A p.V389= | Splice Region (SNP) | VAF 11/183 reads (6%) | called by muse, mutect2
- VRTN | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- WARS1 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 15/409 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- WBP11 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 231/870 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF474 | c.1043T>G p.I348S | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF783 | c.423G>A p.V141= | Splice Region (SNP) | VAF 80/991 reads (8%) | called by muse, mutect2
- AAR2 | c.849G>T p.R283= | Silent (SNP) | VAF 24/462 reads (5%) | called by muse, mutect2
- ANGEL1 | c.462G>A p.S154= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs757378080; called by mutect2, varscan2
- ANGEL2 | c.1083T>C p.Y361= | Silent (SNP) | VAF 98/169 reads (58%) | called by muse, mutect2, varscan2
- ATP10A | c.1068A>G p.T356= | Silent (SNP) | VAF 20/161 reads (12%) | called by mutect2, varscan2
- C3orf38 | c.99C>T p.V33= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- DYSF | c.4536G>A p.V1512= | Silent (SNP) | VAF 39/610 reads (6%) | called by muse, mutect2
- KIAA1549 | c.1467T>C p.P489= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as rs1202974185; called by muse, mutect2, varscan2
- KMT2C | c.14064C>A p.T4688= | Silent (SNP) | VAF 58/211 reads (27%) | called by muse, mutect2, varscan2
- LDHAL6B | c.669T>A p.I223= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- MRC2 | c.3201C>T p.S1067= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- MTDH | c.1485T>C p.T495= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs1464198762, COSV100292745; called by muse, mutect2, varscan2
- NEU1 | c.384C>T p.V128= | Silent (SNP) | VAF 113/173 reads (65%) | catalogued as COSV99999494; called by muse, mutect2, varscan2
- NWD1 | c.3522G>A p.V1174= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as rs1206379273; called by muse, mutect2, varscan2
- OPN4 | c.1041C>T p.P347= | Silent (SNP) | VAF 92/300 reads (31%) | called by muse, mutect2, varscan2
- PIDD1 | c.150G>A p.L50= | Silent (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- PSD3 | c.1527A>C p.A509= | Silent (SNP) | VAF 319/1249 reads (26%) | called by muse, mutect2, varscan2
- TRPC4 | c.30T>G p.V10= | Silent (SNP) | VAF 95/184 reads (52%) | called by muse, mutect2, varscan2
- TSNAX | c.555C>A p.V185= | Silent (SNP) | VAF 259/907 reads (29%) | called by muse, mutect2, varscan2
- VARS2 | c.2217C>T p.V739= | Silent (SNP) | VAF 157/342 reads (46%) | called by muse, mutect2, varscan2
- ZNF484 | c.465T>C p.Y155= | Silent (SNP) | VAF 61/206 reads (30%) | called by muse, mutect2, varscan2
- ZNF831 | c.2625G>A p.Q875= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV64041061; called by muse, mutect2, varscan2
- ATAD3B | c.*240G>A | 3'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as rs1412771247; called by muse, mutect2, varscan2
- SH2D6 | n.433G>A | RNA (SNP) | VAF 4/26 reads (15%) | catalogued as rs747754782; called by mutect2, varscan2
